Somatic mutation profile of tumor specimen TCGA-B6-A0IH-01A (aliquot TCGA-B6-A0IH-01A-11D-A10Y-09) from TCGA case TCGA-B6-A0IH, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-B6-A0IH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68cd8f80-6e62-4d6c-8473-6eba14e52b4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0IH-10A (Blood Derived Normal), aliquot TCGA-B6-A0IH-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df80e2a1-bf40-480c-bfca-35b867b5c750

The open-access MAF lists 39 somatic variants for this specimen: 35 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Nonsense Mutation 3, Silent 3, Frame Shift Del 1, 3'UTR 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGGF1 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.946); catalogued as rs914424358, COSV100462185; called by muse, mutect2
- BCAN | c.2569C>T p.R857* | Nonsense Mutation (SNP) | VAF 10/125 reads (8%) | catalogued as COSV100227937, COSV100228178; called by muse, mutect2
- CFAP74 | c.4270G>A p.V1424M | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1281356386, COSV60586471; called by muse, mutect2
- CLCA1 | c.2081G>A p.G694E | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.356); catalogued as rs368950561, COSV99322190; called by muse, mutect2, varscan2
- CNGA2 | c.1021A>T p.T341S | Missense Mutation (SNP) | VAF 41/398 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100323916; called by muse, mutect2, varscan2
- CPEB3 | c.19A>C p.M7L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.354); catalogued as COSV99800485; called by muse, mutect2
- CYLC2 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV66337460; called by muse, mutect2, varscan2
- DCHS1 | c.7756G>A p.V2586M | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs747141130, COSV54996502; called by muse, mutect2, varscan2
- FRMD4B | c.2498A>G p.Y833C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101273664; called by muse, mutect2
- GRB10 | c.1618A>T p.K540* (on ENST00000398812; = p.K494* on NM_001001549.3) | Nonsense Mutation (SNP) | VAF 67/197 reads (34%) | catalogued as COSV60010295, COSV60012976; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2462A>C p.N821T | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as COSV63100348; called by muse, mutect2, varscan2
- HSPA2 | c.1782G>T p.E594D | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.327); catalogued as COSV99905123; called by muse, mutect2
- KRT9 | c.773A>G p.N258S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as rs779433821, COSV55853036; called by muse, mutect2, varscan2
- LCOR | c.2216A>T p.Q739L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV53715720; called by muse, mutect2, varscan2
- LCT | c.914A>T p.N305I | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as COSV51548825; called by muse, mutect2, varscan2
- MINAR1 | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV59582847; called by muse, mutect2, varscan2
- MTM1 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV60334913; called by muse, mutect2, varscan2
- NFE2 | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100380851; called by muse, mutect2, varscan2
- OR1Q1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.98); catalogued as rs756129489, COSV52917127; called by muse, mutect2, varscan2
- PFKM | c.1367T>C p.V456A | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV56657236; called by muse, mutect2, varscan2
- PLEKHM2 | c.2819A>G p.D940G | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV99606788; called by muse, mutect2
- RBMX | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as COSV100284507; called by muse, mutect2
- RGR | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.084); catalogued as COSV100812969; called by muse, mutect2
- RMI1 | c.1370A>G p.Q457R | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as COSV57936179; called by muse, mutect2, varscan2
- RUNX1 | c.715C>T p.Q239* (on ENST00000344691 / NM_001001890.3; = p.Q266* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 80/341 reads (23%) | catalogued as COSV55873431; called by muse, mutect2, varscan2
- SDK2 | c.5116G>A p.A1706T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1314052840, COSV66185623; called by muse, mutect2, varscan2
- SLC22A14 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs775094730, COSV56197652; called by muse, mutect2, varscan2
- TANC2 | c.5350C>T p.P1784S | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.508); catalogued as COSV67334112; called by muse, mutect2, varscan2
- XPO6 | c.1280A>G p.Y427C | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV58966206; called by muse, mutect2, varscan2
- ZDHHC21 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756767150, COSV66613358; called by muse, mutect2, varscan2
- ZFHX4 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 21/295 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.577); catalogued as rs113917559, COSV50870611; called by muse, mutect2
- CDH1 | c.849_863del p.E283_T287del | In Frame Del (DEL) | VAF 33/106 reads (31%) | called by mutect2, pindel, varscan2
- IL9R | c.133dup p.E45Gfs*8 | Frame Shift Ins (INS) | VAF 64/643 reads (10%) | called by mutect2, pindel, varscan2
- RFX3 | c.137_138del p.V46Afs*49 | Frame Shift Del (DEL) | VAF 23/214 reads (11%) | called by pindel, varscan2
- SPATA31A1 | c.3958C>T p.P1320S | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- DDX54 | c.2211G>A p.K737= | Silent (SNP) | VAF 24/183 reads (13%) | catalogued as COSV58373387; called by muse, mutect2, varscan2
- GPR139 | c.765G>A p.A255= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as rs1303527167, COSV58502068; called by muse, mutect2, varscan2
- HERC2 | c.14397C>T p.I4799= | Silent (SNP) | VAF 49/161 reads (30%) | catalogued as rs563175513, COSV55322636; called by muse, mutect2, varscan2
- DUSP13 | c.*180C>T | 3'UTR (SNP) | VAF 7/55 reads (13%) | catalogued as COSV57814335; called by muse, mutect2, varscan2
